MMRF case MMRF_1819 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bac9570f-9aee-408f-b17c-c67665a0ccf6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 628 days (1.7 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.1 years (24,865 days); ISS stage: II; Days to last known disease status: 628 days (1.7 years); Days to last follow up: 628 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 35 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 766 days (2.1 years).

Follow-up (2 entries)
- Days to follow up: -34 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 628.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Blood Urea Nitrogen 11.4 mmol/L.
- Beta 2 Microglobulin 3.2 µg/mL.
- Immunoglobulin A 0.2 g/L.
- Absolute Neutrophil 5.9 ×10⁹/L.
- Immunoglobulin M 0.04 g/L.
- Platelets 237 ×10⁹/L.
- Glucose 11.2 mmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL.
- M Protein 2.1 g/dL.
- Total Protein 9.4 g/dL.
- Calcium 2.23 mmol/L.
- Hemoglobin 6.7 mmol/L.
- Albumin 29 g/L.
- Creatinine 134 µmol/L.
- Leukocytes 7.1 ×10⁹/L.
- Immunoglobulin G 26.7 g/L.
- Lactate Dehydrogenase 2.97 µkat/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.343 mg/dL.

Other clinical attributes
- Day -34: Weight: 69 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1819_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -34 days.
- Sample MMRF_1819_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -34 days.
